MMRF case MMRF_1992 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/26ff983c-83fe-46a0-a3d4-406e2110116a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.6 years (19,595 days); ISS stage: III; Days to last known disease status: 975 days (2.7 years); Days to last follow up: 975 days (2.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 111 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 19 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 19 days; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 166 days; Days to treatment end: 166 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 167 days; Days to treatment end: 167 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 467 days (1.3 years); Days to treatment end: 653 days (1.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 467 days (1.3 years); Days to treatment end: 659 days (1.8 years).
   Treatment given: Therapeutic agents: Panobinostat; Regimen or line of therapy: Second line of therapy; Days to treatment start: 467 days (1.3 years); Days to treatment end: 655 days (1.8 years).
   Treatment given: Therapeutic agents: Dexamethasone + Elotuzumab + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 701 days (1.9 years); Days to treatment end: 786 days (2.2 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 811 days (2.2 years); Days to treatment end: 961 days (2.6 years).
   Treatment given: Therapeutic agents: Daratumumab + Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 975 days (2.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 3): M Protein 6.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1300 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 93.1 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 24.3 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 11.8 ×10⁹/L; Absolute Neutrophil 6.61 ×10⁹/L; Platelets 294 ×10⁹/L; Creatinine 390 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 3.35 mmol/L; Albumin 37 g/L; Total Protein 13.6 g/dL; Glucose 6.11 mmol/L.
- Day 93 (ECOG 3): M Protein 0.86 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.66 g/L; Hemoglobin 8 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 6.05 mmol/L.
- Day 191 (ECOG 0): M Protein 1.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.086 mg/dL; Immunoglobulin G 17.8 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 1.02 g/L; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.81 ×10⁹/L; Platelets 337 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 4.62 mmol/L.
- Day 261 (ECOG 0): M Protein 1.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.092 mg/dL; Immunoglobulin G 17.5 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.58 mmol/L; Albumin 46 g/L; Total Protein 7.9 g/dL; Glucose 4.35 mmol/L.
- Day 359 (ECOG 0): M Protein 1.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.104 mg/dL; Immunoglobulin G 15.6 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.55 mmol/L; Albumin 45 g/L; Total Protein 7.9 g/dL; Glucose 4.62 mmol/L.
- Day 450 (ECOG 0): M Protein 1.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 32.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 17.3 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 2.04 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.48 mmol/L; Albumin 47 g/L; Total Protein 8.2 g/dL; Glucose 4.29 mmol/L.
- Day 534: M Protein 0.99 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 23.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.698 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 4.4 mmol/L.
- Day 597 (ECOG 0): M Protein 1.02 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 27.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.24 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 6.22 mmol/L.
- Day 681 (ECOG 0): M Protein 1.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 34.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 22.5 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.31 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 7.7 g/dL; Glucose 4.4 mmol/L.
- Day 800 (ECOG 0): M Protein 1.58 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.043 mg/dL; Immunoglobulin G 24.8 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 2.22 µg/mL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 1.98 ×10⁹/L; Platelets 317 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 4.46 mmol/L.
- Day 894 (ECOG 1): M Protein 1.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.084 mg/dL; Immunoglobulin G 23.2 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 266 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 7.9 g/dL; Glucose 4.79 mmol/L.
- Day 975 (ECOG 0): M Protein 1.95 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 42.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.088 mg/dL; Immunoglobulin G 25.8 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.82 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 8.5 g/dL; Glucose 7.81 mmol/L.

Other clinical attributes
- Day 1: Weight: 74 kg; Height: 177 cm.

Biospecimens (4 samples)
- Sample MMRF_1992_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1992_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_1992_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_1992_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 450 days (1.2 years).
